Somatic mutation profile of tumor specimen MMRF_2231_1_BM_CD138pos (aliquot MMRF_2231_1_BM_CD138pos_T1_KHS5U_L08817) from MMRF case MMRF_2231, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,049 days).
Specimen MMRF_2231_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecde8ba5-c262-4dbd-879a-c4c6689190eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2231_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2231_1_PB_Whole_C2_KHS5U_L08779; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28ddcc89-7094-47a7-8fa1-890c89d10afd

The open-access MAF lists 134 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 40, Intron 13, Silent 10, 5'UTR 6, 3'Flank 4, 5'Flank 4, Nonsense Mutation 3, RNA 3, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as rs1555168505, CM152042, CS941454, COSV61527689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs762034429; called by muse, mutect2, varscan2
- CACNA1E | c.6148C>T p.R2050C (on ENST00000367573 / NM_001205293.3; = p.R2007C on NM_000721.4) | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs769307233, COSV62384798; called by muse, mutect2, varscan2
- CELF3 | c.630C>T p.A210= | Splice Region (SNP) | VAF 53/185 reads (29%) | catalogued as rs553677476; called by muse, mutect2, varscan2
- CLEC4C | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1049599097, COSV63582734; called by muse, mutect2, varscan2
- CYLD | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as COSV61095187; called by muse, mutect2, varscan2
- DNAJC22 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101222577; called by muse, mutect2, varscan2
- GDPD1 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.073); catalogued as COSV52385267; called by muse, mutect2, varscan2
- IGLV4-60 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs540014769; called by muse, mutect2, varscan2
- KLHL13 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs767019533; called by muse, mutect2, varscan2
- KRT5 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs895084041, CM141657; called by muse, mutect2, varscan2
- MB21D2 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as rs147668431; called by muse, mutect2, varscan2
- PTDSS2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs1164971971, COSV100339394; called by muse, mutect2, varscan2
- RADX | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs747290932; called by muse, mutect2, varscan2
- SPATA17 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 48/319 reads (15%) | catalogued as rs756118007; called by muse, mutect2, varscan2
- TMEM11 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1027658928; called by muse, mutect2, varscan2
- UBQLN3 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 142/275 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1164267569; called by muse, mutect2, varscan2
- VWA5B1 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs532220674, COSV99055995; called by muse, mutect2, varscan2
- ZNF490 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV61009278; called by muse, mutect2, varscan2
- ZNF490 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs760320609; called by muse, mutect2, varscan2
- ARX | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BCL2L12 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BMS1 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C2orf16 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CEACAM1 | c.856A>C p.I286L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- DOCK11 | c.2163C>G p.H721Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DUSP12 | c.802T>G p.Y268D | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- FNIP2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GABBR1 | c.2648A>G p.N883S | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GMPPA | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR150 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- GPRIN2 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- HOXA3 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGHV2-70 | c.209_217del p.A70_I72del | In Frame Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- ITPR1 | c.6293C>G p.A2098G (on ENST00000354582; = p.A2043G on NM_002222.7) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KITLG | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYST | c.10508C>T p.A3503V | Missense Mutation (SNP) | VAF 120/232 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); called by muse, varscan2
- MGAM | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MYO18B | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.28); called by muse, mutect2
- NPR1 | c.2595G>C p.E865D | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NRP2 | c.2563_2566del p.E855Rfs*17 (on ENST00000360409 / NM_201266.2; = p.E850Rfs*17 on NM_003872.3) | Frame Shift Del (DEL) | VAF 56/136 reads (41%) | called by mutect2, pindel, varscan2
- OR6Q1 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 179/359 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHKA2 | c.1613T>C p.M538T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PHLPP2 | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RASGRP2 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RP1 | c.1450A>C p.N484H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RTF2 | c.591+2_591+8del p.X197_splice | Splice Site (DEL) | VAF 22/65 reads (34%) | called by mutect2, varscan2
- SLC5A12 | c.826T>A p.L276M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDRP | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THBS2 | c.2661T>A p.H887Q | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- TTN | c.25484A>G p.K8495R (on ENST00000591111; = p.K7568R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/196 reads (53%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIK1 | c.1022A>C p.H341P | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF500 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF735 | c.1185T>A p.S395R | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AGTRAP | c.426C>T p.P142= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as rs563810058; called by muse, mutect2
- CACNA1C | c.1782C>T p.F594= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs374976163; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF10 | c.195C>A p.A65= | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- GDF2 | c.627C>T p.S209= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs374479283; called by muse, mutect2
- IRX3 | c.657G>A p.E219= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- LTB | c.129G>A p.V43= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs769689253; called by muse, mutect2, varscan2
- PGM1 | c.1416T>C p.D472= | Silent (SNP) | VAF 77/160 reads (48%) | called by muse, mutect2, varscan2
- PRDM1 | c.222T>C p.G74= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs370126650, COSV64849759; called by muse, mutect2, varscan2
- U2AF1L4 | c.555C>G p.L185= (on ENST00000412391; = p.S127C on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs1019608994; called by muse, mutect2, varscan2
- UBR2 | c.2481A>G p.G827= | Silent (SNP) | VAF 76/198 reads (38%) | called by muse, mutect2, varscan2
- ACTR6 | c.*134A>G | 3'UTR (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2, varscan2
- ADAM17 | c.843+830C>T | Intron (SNP) | VAF 9/231 reads (4%) | called by muse, mutect2
- AHR | c.-134G>A | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- AJAP1 | c.-397C>A | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- ANKRD26 | c.1635+2060T>A | Intron (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- ANLN | c.*625T>A | 3'UTR (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- ARID5A | c.312+61C>T | Intron (SNP) | VAF 32/70 reads (46%) | catalogued as rs1200088448; called by muse, varscan2
- ATP2A2 | c.2608-23A>G | Intron (SNP) | VAF 51/166 reads (31%) | catalogued as rs373821082; called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4662T>G | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021505 A>G | 5'Flank (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- BIN1 | c.1240-168G>A | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- BMP6 | c.*125C>T | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- BRI3BP | c.*2239C>G | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- BRWD3 | c.*2753C>A | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.*4272A>G | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65883833 A>G | 3'Flank (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- CLN5 | chr13:76991067 C>T | 5'Flank (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- CNKSR2 | c.*220A>C | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- COL5A3 | c.*604C>T | 3'UTR (SNP) | VAF 73/112 reads (65%) | called by muse, mutect2, varscan2
- CTCFL | c.1674+959G>A | Intron (SNP) | VAF 39/97 reads (40%) | catalogued as rs755876635; called by muse, mutect2, varscan2
- CUX1 | c.*5242T>A | 3'UTR (SNP) | VAF 104/256 reads (41%) | called by muse, mutect2, varscan2
- DCTN2 | c.*423A>G | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs925779675; called by muse, mutect2, varscan2
- DSC2 | c.2509-87G>T | Intron (SNP) | VAF 94/222 reads (42%) | catalogued as COSV51864515; called by muse, mutect2, varscan2
- DYNLT3 | c.*1190T>C | 3'UTR (SNP) | VAF 23/207 reads (11%) | called by muse, mutect2, varscan2
- E2F7 | c.*2511_*2516del | 3'UTR (DEL) | VAF 44/96 reads (46%) | called by mutect2, varscan2
- EIF1AD | c.*602T>C | 3'UTR (SNP) | VAF 14/80 reads (18%) | catalogued as rs1200503416; called by muse, mutect2, varscan2
- ENTPD7 | c.*1435G>A | 3'UTR (SNP) | VAF 30/56 reads (54%) | catalogued as rs557538771; called by muse, mutect2, varscan2
- EVC | c.*149G>A | 3'UTR (SNP) | VAF 27/57 reads (47%) | catalogued as rs1328401367, COSV53837967; called by muse, mutect2, varscan2
- GATA4 | chr8:11762296 C>T | 3'Flank (SNP) | VAF 54/75 reads (72%) | catalogued as rs939497305; called by muse, mutect2, varscan2
- GPATCH2 | c.*2917A>T | 3'UTR (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*4081A>C | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- HBE1 | c.-267+36976A>C | Intron (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- HCFC2 | c.*1540C>G | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- HMGN1 | chr21:39349585 C>G | 5'Flank (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- KALRN | c.*1278A>G | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.1424A>C | RNA (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- KIF14 | c.*714T>G | 3'UTR (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- LHX6 | c.*18C>A | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- MAGEA6 | c.*20C>G | 3'UTR (SNP) | VAF 111/302 reads (37%) | called by muse, mutect2, varscan2
- MECP2 | c.-208G>A | 5'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, varscan2
- MED13L | c.*1541A>G | 3'UTR (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- MEI1 | chr22:41697318 T>C | 5'Flank (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- MIR3924 | n.16T>C | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as rs552853745; called by muse, mutect2
- MTHFR | c.*37G>T | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- MTO1 | chr6:73505248 T>C | 3'Flank (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- NAPB | c.179-12T>C | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- NIFK | c.*670dup | 3'UTR (INS) | VAF 29/73 reads (40%) | called by mutect2, pindel, varscan2
- PARP8 | c.*2465C>T | 3'UTR (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- PCDH11X | c.3144+24832T>C | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- PLP1 | c.-109A>T | 5'UTR (SNP) | VAF 69/178 reads (39%) | called by muse, mutect2, varscan2
- PM20D2 | c.*1960T>C | 3'UTR (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- PPP6C | c.*731A>T | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.*2675G>A | 3'UTR (SNP) | VAF 15/52 reads (29%) | catalogued as rs113318977; called by muse, mutect2, varscan2
- RHPN2P1 | n.698T>C | RNA (SNP) | VAF 50/353 reads (14%) | called by muse, mutect2, varscan2
- RIMBP2 | c.*1721G>A | 3'UTR (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- RRS1 | c.*74C>A | 3'UTR (SNP) | VAF 79/230 reads (34%) | called by muse, mutect2, varscan2
- SERP1 | c.*1113A>T | 3'UTR (SNP) | VAF 43/147 reads (29%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*4676C>T | 3'UTR (SNP) | VAF 44/112 reads (39%) | catalogued as rs901681771; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25094244 C>T | 3'Flank (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2, varscan2
- SOX11 | c.*4924C>T | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-38C>A | 5'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- STC2 | c.*3038C>G | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- SUMO3 | c.*634A>T | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- TBR1 | c.*363C>T | 3'UTR (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*1947T>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TMEM9B | c.441+92C>G | Intron (SNP) | VAF 19/247 reads (8%) | called by muse, mutect2
- TNRC6B | c.*11971C>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- TSC2 | c.3884-142G>C | Intron (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- USP54 | c.*820C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- ZIC3 | c.-113G>T | 5'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
